Surgical pathology report (de-identified scan), TCGA case TCGA-22-4593, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4593-01A (Primary Tumor).

[REDACTED] Surgical Pathology

TISSUE DESCRIPTION:

Right lower lobe lung (330 grams, 17 x 9 x 6.5 cm). Superior mediastinal (upper paratracheal, lower paratracheal, right tracheobronchial), inferior mediastinal (subcarinal) and N1 (interlobar) lymph nodes.

DIAGNOSIS:

Lung, right lower lobe, lobectomy: Grade 3 (of 4) invasive squamous cell carcinoma forming a centrally necrotic mass measuring 6 x 6 x 5 cm located 1.5 cm from the bronchial resection margin. The tumor involves the visceral pleura over an area of approximately 3 x 3 cm. The bronchial margin is negative for tumor.

Lymph nodes, superior and inferior mediastinal, N1, excision: Multiple (1 upper paratracheal, 1 lower paratracheal, 2 right tracheobronchial, 3 subcarinal, 3 interlobar) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 4b3c153f-0309-427e-9600-256950c8254e (TCGA-22-4593.D20D26E3-DA2C-4456-894D-6F08D62856EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).